Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6U0, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6U0-01A (Primary Tumor).

Morphology shows pleomorphic cellular astrocytic tumor. Mitotic activity present. Beginning vascular proliferation. Proliferation index 25%. Borderlin case, transition to glioblastoma possible.

Diagnosis

Anaplastic astrocytoma WHO grade III

CCF ICD-O-3
Astrocytoma, grade III
path 9461/3
Astrocytoma anaplastic 9461/3
Site: Brain, supratentorial
C71.0
JW 7/26/13

untranslated original report
is housed at the BCR

Source: NCI Genomic Data Commons file 5cd4b6fb-3254-4cd2-bc24-211afc854158 (TCGA-S9-A6U0.D07453BE-76A4-42D0-B075-BDEA24A294E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).